Somatic mutation profile of tumor specimen MP2PRT-PANYCF-TMP1-A (aliquot MP2PRT-PANYCF-TMP1-A-1-0-D-A82K-36) from MP2PRT case MP2PRT-PANYCF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.1 years (769 days).
Specimen MP2PRT-PANYCF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 677c9225-5e83-49f5-b495-40f7347153dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANYCF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANYCF-NB1-A-1-0-D-A82K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/84143c9e-bad6-4b8f-a2c9-fb21fd435ed5

The open-access MAF lists 143 somatic variants for this specimen: 97 protein-altering or splice-affecting, 39 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 86, Silent 39, Nonsense Mutation 8, 3'UTR 4, Intron 2, 3'Flank 1, Splice Region 1, Nonstop Mutation 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1517G>C p.G506A (on ENST00000288602 / NM_001374244.1; = p.G466A on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 99/361 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as rs121913351, CM115083, COSV56057462, COSV56059390, COSV56070593; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AADACL3 | c.238C>A p.P80T | Missense Mutation (SNP) | VAF 60/328 reads (18%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.506); catalogued as COSV60198634; called by muse, mutect2, varscan2
- ABHD12B | c.464C>T p.S155L (on ENST00000337334 / NM_001206673.2; = p.S78L on NM_181533.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/298 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.067); catalogued as rs750117835; called by muse, mutect2
- ADAM2 | c.970G>A p.D324N | Missense Mutation (SNP) | VAF 107/273 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV55859687; called by muse, mutect2, varscan2
- BCL9 | c.2989C>G p.P997A | Missense Mutation (SNP) | VAF 184/555 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs373872059, COSV52347946; called by muse, mutect2, varscan2
- CAPN14 | c.1331G>A p.R444K | Missense Mutation (SNP) | VAF 12/304 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67290191; called by muse, mutect2
- CAVIN1 | c.663C>G p.I221M | Missense Mutation (SNP) | VAF 179/451 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV63811812; called by muse, mutect2, varscan2
- CCN3 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 10/303 reads (3%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as rs1266217803, COSV99422659; called by muse, mutect2
- CDK13 | c.872C>T p.S291L | Missense Mutation (SNP) | VAF 16/580 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.139); catalogued as rs1476149092; called by muse, mutect2
- CFAP43 | c.2797G>C p.E933Q | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.83); catalogued as COSV53376287; called by muse, mutect2
- CFAP65 | c.448G>A p.E150K (on ENST00000341552 / NM_194302.4; = p.E85K on NM_152389.4) | Missense Mutation (SNP) | VAF 148/356 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.024); catalogued as COSV99838376; called by muse, mutect2, varscan2
- CSMD1 | c.4471G>A p.A1491T (on ENST00000520002; = p.A1490T on NM_033225.6) | Missense Mutation (SNP) | VAF 90/249 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs551222035, COSV59321498; called by muse, mutect2, varscan2
- DYNC2H1 | c.11017C>T p.Q3673* | Nonsense Mutation (SNP) | VAF 64/158 reads (41%) | catalogued as COSV62103462; called by muse, mutect2, varscan2
- EML1 | c.1492G>C p.E498Q | Missense Mutation (SNP) | VAF 36/227 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.05); catalogued as COSV51748584; called by muse, mutect2, varscan2
- FLNC | c.4879C>T p.R1627C | Missense Mutation (SNP) | VAF 32/518 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.095); catalogued as rs760407609, COSV100368599; ClinVar: uncertain significance; called by muse, mutect2
- FOXD4L1 | c.479C>G p.S160W | Missense Mutation (SNP) | VAF 324/1001 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52076158; called by muse, mutect2, varscan2
- HERC2 | c.897G>C p.Q299H | Missense Mutation (SNP) | VAF 18/400 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99873569; called by muse, mutect2
- IL1RAPL1 | c.1150G>C p.E384Q | Missense Mutation (SNP) | VAF 110/147 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56250744; called by muse, mutect2, varscan2
- IRF3 | c.467G>T p.G156V | Missense Mutation (SNP) | VAF 18/499 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as COSV55864642; called by muse, mutect2
- KMT2C | c.12149C>G p.S4050* | Nonsense Mutation (SNP) | VAF 20/320 reads (6%) | catalogued as COSV100070102, COSV51429659, COSV51442169; called by muse, mutect2
- LTN1 | c.469G>C p.D157H | Missense Mutation (SNP) | VAF 87/338 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63733934; called by muse, mutect2, varscan2
- MEPE | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 134/361 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.045); catalogued as COSV63072622; called by muse, mutect2, varscan2
- MUC17 | c.5114C>G p.S1705C | Missense Mutation (SNP) | VAF 20/521 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.323); catalogued as COSV60294229; called by muse, mutect2
- NEDD1 | c.266C>G p.S89C | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768761470, COSV99901130; called by muse, mutect2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 206/408 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR2AJ1 | c.12G>C p.Q4H | Missense Mutation (SNP) | VAF 38/174 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.09); catalogued as COSV59089344; called by muse, mutect2, varscan2
- PAK1 | c.354G>T p.K118N | Missense Mutation (SNP) | VAF 24/428 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV53697667; called by muse, mutect2
- PHF24 | c.1008C>T p.V336= | Splice Region (SNP) | VAF 16/296 reads (5%) | catalogued as rs1563937890; called by muse, mutect2
- PLEKHA7 | c.751C>G p.Q251E | Missense Mutation (SNP) | VAF 44/348 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as COSV63046180, COSV63048000; called by muse, mutect2, varscan2
- RFPL2 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 44/393 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as rs1467653676, COSV50712796; called by muse, mutect2
- SCRT1 | c.939C>G p.F313L | Missense Mutation (SNP) | VAF 32/705 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV59782145; called by muse, mutect2
- SIX5 | c.286G>C p.E96Q | Missense Mutation (SNP) | VAF 292/775 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52181370; called by muse, varscan2
- SP9 | c.635C>G p.S212W | Missense Mutation (SNP) | VAF 252/683 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV67602528; called by muse, mutect2, varscan2
- TAPBP | c.1346C>G p.S449C | Missense Mutation (SNP) | VAF 24/557 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.634); catalogued as COSV101444958; called by muse, mutect2
- TRIM33 | c.2366C>G p.S789* | Nonsense Mutation (SNP) | VAF 14/398 reads (4%) | catalogued as COSV100635192; called by muse, mutect2
- WDR17 | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 45/402 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.668); catalogued as rs201283359; called by muse, mutect2, varscan2
- ZNF18 | c.1021G>C p.E341Q | Missense Mutation (SNP) | VAF 119/397 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs1164843217; called by muse, mutect2, varscan2
- AKT1S1 | c.691G>A p.E231K (on ENST00000344175 / NM_001098633.4; = p.E251K on NM_032375.5) | Missense Mutation (SNP) | VAF 200/548 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- APBB1IP | c.439G>C p.E147Q | Missense Mutation (SNP) | VAF 144/442 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- APLP2 | c.1609G>C p.E537Q | Missense Mutation (SNP) | VAF 19/284 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- ASNS | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 12/305 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.54); called by muse, mutect2
- ASPDH | c.307G>C p.D103H | Missense Mutation (SNP) | VAF 175/507 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- BAZ2B | c.4861C>T p.Q1621* | Nonsense Mutation (SNP) | VAF 49/222 reads (22%) | called by muse, mutect2, varscan2
- BCAT1 | c.1057C>G p.P353A | Missense Mutation (SNP) | VAF 31/277 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- BRCA2 | c.5579A>T p.K1860I | Missense Mutation (SNP) | VAF 53/164 reads (32%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- CARD14 | c.2875G>C p.D959H | Missense Mutation (SNP) | VAF 34/660 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2
- CCDC57 | c.1264G>A p.D422N | Missense Mutation (SNP) | VAF 17/410 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2
- CCNJ | c.510G>A p.M170I | Missense Mutation (SNP) | VAF 135/378 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- CD55 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 62/224 reads (28%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.523); called by muse, mutect2, varscan2
- CDH18 | c.415C>G p.L139V | Missense Mutation (SNP) | VAF 159/388 reads (41%) | SIFT tolerated (0.56); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CENPVL3 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 41/407 reads (10%) | SIFT tolerated, low confidence (1); called by muse, mutect2, varscan2
- CEP63 | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 93/271 reads (34%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNNM1 | c.2429G>A p.G810E | Missense Mutation (SNP) | VAF 18/534 reads (3%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.452); called by muse, mutect2
- DDX59 | c.730C>G p.L244V | Missense Mutation (SNP) | VAF 110/324 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.198); called by muse, varscan2
- DNAAF2 | c.110C>G p.S37C | Missense Mutation (SNP) | VAF 36/589 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.065); called by muse, mutect2
- DST | c.19031C>G p.A6344G (on ENST00000361203 / NM_001374722.1; = p.A4041G on NM_015548.5) | Missense Mutation (SNP) | VAF 23/384 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); called by muse, mutect2
- EML3 | c.1721G>A p.G574E | Missense Mutation (SNP) | VAF 135/414 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FOXD4L4 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 74/1372 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.059); called by muse, mutect2
- FRG2C | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 83/1037 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); called by muse, mutect2
- FSIP2 | c.8797C>G p.L2933V | Missense Mutation (SNP) | VAF 16/268 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.578); called by muse, mutect2
- FSIP2 | c.9218C>G p.S3073* | Nonsense Mutation (SNP) | VAF 14/262 reads (5%) | called by muse, mutect2
- FYCO1 | c.4028C>T p.S1343F | Missense Mutation (SNP) | VAF 21/252 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GEM | c.179C>T p.S60F | Missense Mutation (SNP) | VAF 49/435 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- HELLS | c.35C>G p.S12W | Missense Mutation (SNP) | VAF 51/182 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- IGHV4-61 | c.352_353insTGGGAA p.A117_R118insMG | In Frame Ins (INS) | VAF 6/20 reads (30%) | called by pindel, varscan2
- IGLV4-69 | c.357_359delinsGTGAGAC p.I119Mfs*2 | Nonsense Mutation (INS) | VAF 47/142 reads (33%) | called by pindel, varscan2*
- ITCH | c.142G>C p.D48H | Missense Mutation (SNP) | VAF 16/418 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KAT6B | c.2458G>C p.D820H | Missense Mutation (SNP) | VAF 20/374 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KIAA0586 | c.3469C>T p.H1157Y (on ENST00000619416 / NM_001244190.2; = p.H1096Y on NM_014749.5) | Missense Mutation (SNP) | VAF 79/208 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- LEMD3 | c.377C>T p.S126F | Missense Mutation (SNP) | VAF 35/732 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); called by muse, mutect2
- MBL2 | c.565G>C p.E189Q | Missense Mutation (SNP) | VAF 155/452 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- MROH7 | c.3764C>T p.S1255L | Missense Mutation (SNP) | VAF 29/268 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- MYO9A | c.6541C>G p.H2181D | Missense Mutation (SNP) | VAF 12/319 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.64); called by muse, mutect2
- NEMP1 | c.532G>C p.D178H | Missense Mutation (SNP) | VAF 46/211 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NPFFR2 | c.1017C>G p.I339M | Missense Mutation (SNP) | VAF 24/478 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2
- OGDH | c.335C>T p.S112F | Missense Mutation (SNP) | VAF 21/583 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2
- OR1K1 | c.572C>G p.S191C | Missense Mutation (SNP) | VAF 24/556 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PHKA1 | c.1835G>A p.C612Y | Missense Mutation (SNP) | VAF 50/182 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); called by muse, varscan2
- PHKA2 | c.3274C>G p.L1092V | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.751); called by muse, mutect2
- PHLPP2 | c.247G>C p.E83Q | Missense Mutation (SNP) | VAF 95/261 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PLPPR1 | c.147C>G p.F49L | Missense Mutation (SNP) | VAF 28/491 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); called by muse, mutect2
- PRICKLE2 | c.229C>T p.Q77* (on ENST00000295902; = p.Q21* on NM_198859.4) | Nonsense Mutation (SNP) | VAF 28/601 reads (5%) | called by muse, mutect2
- PRR33 | c.1318C>G p.R440G | Missense Mutation (SNP) | VAF 46/746 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.088); called by muse, mutect2
- PTCH1 | c.4343G>T p.*1448Lext*2 | Nonstop Mutation (SNP) | VAF 20/258 reads (8%) | called by muse, mutect2
- PTPRM | c.2764G>C p.E922Q | Missense Mutation (SNP) | VAF 94/273 reads (34%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- SCRT1 | c.773C>T p.S258L | Missense Mutation (SNP) | VAF 35/698 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); called by muse, mutect2
- SPINK5 | c.3013C>G p.L1005V | Missense Mutation (SNP) | VAF 15/258 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SPINT2 | c.149C>G p.S50C | Missense Mutation (SNP) | VAF 140/339 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SYNE1 | c.1980G>A p.M660I (on ENST00000367255 / NM_182961.4; = p.M667I on NM_033071.3) | Missense Mutation (SNP) | VAF 104/280 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- TAF4 | c.902C>A p.A301D | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.255); called by muse, varscan2
- TCF4 | c.673G>C p.D225H | Missense Mutation (SNP) | VAF 110/312 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- TEX10 | c.2682G>C p.L894F | Missense Mutation (SNP) | VAF 95/221 reads (43%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TGS1 | c.853G>C p.E285Q | Missense Mutation (SNP) | VAF 44/261 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- TPR | c.6889G>A p.E2297K | Missense Mutation (SNP) | VAF 54/281 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TSPAN32 | c.868C>A p.L290M | Missense Mutation (SNP) | VAF 49/380 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- YTHDC1 | c.1891C>T p.Q631* (on ENST00000344157 / NM_001031732.4; = p.Q613* on NM_133370.4) | Nonsense Mutation (SNP) | VAF 15/351 reads (4%) | called by muse, mutect2
- ZNF304 | c.184G>C p.E62Q | Missense Mutation (SNP) | VAF 20/286 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.172); called by muse, mutect2
- ADCY3 | c.555C>G p.L185= | Silent (SNP) | VAF 18/420 reads (4%) | called by muse, mutect2
- AIFM2 | c.651C>T p.L217= | Silent (SNP) | VAF 35/286 reads (12%) | called by muse, mutect2, varscan2
- AJM1 | c.267C>G p.R89= | Silent (SNP) | VAF 18/378 reads (5%) | called by muse, mutect2
- ANO5 | c.585G>C p.R195= | Silent (SNP) | VAF 54/330 reads (16%) | called by muse, mutect2, varscan2
- ASTN1 | c.1281C>T p.F427= | Silent (SNP) | VAF 14/284 reads (5%) | called by muse, mutect2
- ATP13A5 | c.2787C>G p.L929= | Silent (SNP) | VAF 8/202 reads (4%) | catalogued as COSV100665574, COSV60874884; called by muse, mutect2
- C10orf71 | c.2655C>T p.L885= | Silent (SNP) | VAF 15/525 reads (3%) | called by muse, mutect2
- CACNA2D3 | c.2880G>A p.Q960= | Silent (SNP) | VAF 65/195 reads (33%) | catalogued as COSV55546041; called by muse, mutect2, varscan2
- CCAR2 | c.2676C>G p.L892= | Silent (SNP) | VAF 201/499 reads (40%) | called by muse, mutect2, varscan2
- CCN1 | c.912G>A p.L304= | Silent (SNP) | VAF 164/455 reads (36%) | catalogued as rs1168911196, COSV71704445; called by muse, mutect2, varscan2
- CDC5L | c.2044C>T p.L682= | Silent (SNP) | VAF 18/332 reads (5%) | catalogued as COSV65175493; called by muse, mutect2
- CDCA2 | c.2481G>A p.R827= | Silent (SNP) | VAF 45/546 reads (8%) | called by muse, mutect2
- CFTR | c.564G>A p.L188= | Silent (SNP) | VAF 29/123 reads (24%) | called by muse, mutect2, varscan2
- CNTNAP4 | c.339C>T p.F113= | Silent (SNP) | VAF 13/370 reads (4%) | called by muse, mutect2
- COL18A1 | c.1602C>T p.V534= (on ENST00000359759 / NM_130444.3; = p.V299= on NM_030582.4) | Silent (SNP) | VAF 38/1060 reads (4%) | called by muse, mutect2
- CSNKA2IP | c.837G>A p.Q279= | Silent (SNP) | VAF 26/340 reads (8%) | called by muse, mutect2
- CTNNA2 | c.2400G>A p.Q800= | Silent (SNP) | VAF 70/225 reads (31%) | catalogued as rs768444465; called by muse, mutect2, varscan2
- GPC5 | c.522C>G p.V174= | Silent (SNP) | VAF 100/316 reads (32%) | called by muse, mutect2, varscan2
- HEATR1 | c.1656G>C p.V552= | Silent (SNP) | VAF 10/84 reads (12%) | called by muse, mutect2, varscan2
- IQCN | c.3483G>A p.A1161= | Silent (SNP) | VAF 137/408 reads (34%) | catalogued as rs145211783; called by muse, mutect2, varscan2
- IRAG2 | c.3393G>A p.V1131= (on ENST00000636465; = p.V176= on NM_006152.4 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 128/414 reads (31%) | called by muse, mutect2, varscan2
- KCNS2 | c.759C>T p.L253= | Silent (SNP) | VAF 26/397 reads (7%) | catalogued as COSV54639520; called by muse, mutect2
- KLHDC7A | c.1761G>A p.L587= | Silent (SNP) | VAF 36/718 reads (5%) | called by muse, mutect2
- MAGEC1 | c.2277C>T p.F759= | Silent (SNP) | VAF 163/281 reads (58%) | catalogued as COSV99595803; called by muse, mutect2, varscan2
- OR11L1 | c.831C>T p.F277= | Silent (SNP) | VAF 58/278 reads (21%) | catalogued as rs777160400; called by muse, mutect2, varscan2
- PLK5 | c.894C>G p.L298= | Silent (SNP) | VAF 28/664 reads (4%) | called by muse, mutect2
- PPM1N | c.306C>T p.L102= | Silent (SNP) | VAF 38/794 reads (5%) | catalogued as rs774525986, COSV55593450, COSV55595252; called by muse, mutect2
- PPP1R10 | c.270C>G p.L90= | Silent (SNP) | VAF 120/344 reads (35%) | called by muse, mutect2, varscan2
- PRKCG | c.801C>G p.L267= | Silent (SNP) | VAF 43/490 reads (9%) | called by muse, mutect2
- PTPRT | c.1266C>T p.L422= | Silent (SNP) | VAF 221/585 reads (38%) | called by muse, mutect2, varscan2
- PYHIN1 | c.1050A>T p.T350= | Silent (SNP) | VAF 14/314 reads (4%) | called by muse, mutect2
- RSPH3 | c.1509G>A p.L503= (on ENST00000252655; = p.L361= on NM_031924.8) | Silent (SNP) | VAF 19/426 reads (4%) | called by muse, mutect2
- SEZ6L2 | c.1881G>C p.L627= (on ENST00000308713 / NM_001114099.3; = p.L557= on NM_012410.4) | Silent (SNP) | VAF 132/374 reads (35%) | called by muse, mutect2, varscan2
- SLC35F2 | c.900C>G p.L300= | Silent (SNP) | VAF 102/324 reads (31%) | called by muse, mutect2, varscan2
- STAT5B | c.462C>G p.V154= | Silent (SNP) | VAF 15/362 reads (4%) | called by muse, mutect2
- TMEM126B | c.312G>A p.L104= | Silent (SNP) | VAF 26/308 reads (8%) | called by muse, mutect2
- TMEM259 | c.331C>T p.L111= | Silent (SNP) | VAF 58/590 reads (10%) | called by muse, mutect2
- USP46 | c.969C>T p.F323= | Silent (SNP) | VAF 28/276 reads (10%) | catalogued as rs771644189; called by muse, mutect2
- ZNF133 | c.1509C>T p.F503= (on ENST00000316358 / NM_001352454.2; = p.F502= on NM_003434.7 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 30/606 reads (5%) | called by muse, mutect2
- ARMCX4 | c.1038+4240G>C | Intron (SNP) | VAF 13/242 reads (5%) | called by muse, mutect2
- LCORL | chr4:17877999 C>T | 3'Flank (SNP) | VAF 124/325 reads (38%) | called by muse, mutect2, varscan2
- STAT5B | c.*417G>T | 3'UTR (SNP) | VAF 16/449 reads (4%) | catalogued as COSV53186130; called by muse, mutect2
- STAT5B | c.*271G>C | 3'UTR (SNP) | VAF 22/593 reads (4%) | called by muse, mutect2
- TGFBR3L | c.*103G>A | 3'UTR (SNP) | VAF 178/557 reads (32%) | called by muse, mutect2, varscan2
- TTC17 | c.2252-7075G>A | Intron (SNP) | VAF 63/298 reads (21%) | called by muse, mutect2, varscan2
- U2AF1L4 | c.*103C>A | 3'UTR (SNP) | VAF 16/412 reads (4%) | called by muse, mutect2
